National Lung Screening Trial (NLST) participant 213506 — screening results and CT findings
Open-access record from the public subset of National Lung Screening Trial clinical data distributed by the NCI Imaging Data Commons (release v24, collection nlst). NLST enrolled current and former heavy smokers aged 55–74 in 2002–2004 and randomised them to three annual screens (T0, T1, T2) with low-dose CT or chest radiography, with follow-up through 2009. Coded values are written out from the NLST data dictionaries; day counts are days from randomisation.
https://doi.org/10.7937/TCIA.HMQ8-J677

Participant
Age at randomisation: 58 years; Gender: female; Race: White; Cigarette smoking status at randomisation: former smoker (to be eligible, former smokers had quit within the previous 15 years); Enrolled through an American College of Radiology Imaging Network (ACRIN) centre (from the participant ID range).

Screening results (official result of each annual screen after comparison with prior images; this participant has CT screening exam records, so these are low-dose CT screens)
- T0 (day 0): Positive, change unspecified: nodule(s) >= 4 mm or enlarging nodule(s), mass(es), or other non-specific abnormalities suspicious for lung cancer. Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 37 effective mAs, display field of view 34 cm, reconstruction filter Siemens B50F / Siemens B30.
- T1 (day 368): Positive, no significant change: stable abnormalities potentially related to lung cancer, unchanged since the prior screening exam. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 35 effective mAs, display field of view 32 cm, reconstruction filter Siemens, other.
- T2 (day 795): Positive, other. Isolation read, before comparison with prior images: positive (nodule(s) >= 4 mm, mass or other suspicious abnormality). Exam quality: diagnostic CT; technique as recorded on the form: 120 kVp, 35 effective mAs, display field of view 33 cm, reconstruction filter Siemens, other.

Abnormalities recorded by the reading radiologist on the CT screens (9 abnormalities; numbered within each screening year; size, margins, attenuation and location were collected only for non-calcified nodules or masses of at least 4 mm; interval-change items come from the comparison read)
- T0 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 8 mm, longest perpendicular diameter 6 mm; margins poorly defined; predominant attenuation soft tissue; greatest diameter on CT slice 122.
- T0 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 5 mm, longest perpendicular diameter 5 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 123.
- T1 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 6 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 127; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T1 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 4 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 127; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T1 abnormality 3: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 1: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 12 mm, longest perpendicular diameter 7 mm; margins poorly defined; predominant attenuation soft tissue; greatest diameter on CT slice 130; pre-existing on earlier images (earliest visible day 0); interval growth; no suspicious change in attenuation.
- T2 abnormality 2: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the left lower lobe; longest diameter 4 mm, longest perpendicular diameter 4 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 131; pre-existing on earlier images (earliest visible day 0); no interval growth; no suspicious change in attenuation.
- T2 abnormality 3: Non-calcified micronodule(s) (opacity < 4 mm diameter).
- T2 abnormality 4: Non-calcified nodule or mass (opacity >= 4 mm diameter); epicentre in the right middle lobe; longest diameter 6 mm, longest perpendicular diameter 5 mm; margins smooth; predominant attenuation soft tissue; greatest diameter on CT slice 131; new (not pre-existing on earlier images).

Follow-up
No confirmed lung cancer during the trial; Last known free of lung cancer: day 2,421.
